TARGET case TARGET-20-D87-EC-CBFA2T3_GLIS2-scbulkleftovers — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/7f8c47fa-5ee5-4432-89da-a47c9046e740

Biospecimens (1 sample)
- Sample TARGET-20-D87-EC-CBFA2T3_GLIS2-scbulkleftovers-85: Sample type: Next Generation Cancer Model; Tissue type: Tumor.
